Somatic mutation profile of cancer-model specimen HCM-BROD-1124-C16-85B (3D Organoid, passage 4; aliquot HCM-BROD-1124-C16-85B-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-1124-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 62.6 years (22,882 days).
Specimen HCM-BROD-1124-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8bdf8d8-8f48-42bf-99a2-94e54d688b67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1124-C16-10A (Blood Derived Normal), aliquot HCM-BROD-1124-C16-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56bdd8d7-7856-4b3c-bd9f-c755ce141021

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Del 2, Frame Shift Ins 1, Nonstop Mutation 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 203/520 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs1344172059, COSV56859663; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 98/283 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.219); catalogued as rs1363649764, COSV100608968; called by muse, mutect2, varscan2
- CES2 | c.423G>A p.P141= | Splice Region (SNP) | VAF 117/118 reads (99%) | catalogued as rs757492387, COSV57697090; called by muse, varscan2
- CHSY3 | c.2409G>T p.W803C | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767792548; called by muse, mutect2
- COL20A1 | c.2902G>A p.G968R | Missense Mutation (SNP) | VAF 73/610 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753868347; called by muse, mutect2, varscan2
- DUSP12 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769804396; called by muse, varscan2
- EIF2D | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs34138767, COSV55113559; called by muse, mutect2
- TNFRSF6B | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 110/1567 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs202169963; called by muse, mutect2
- ABHD13 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADCY2 | c.1971dup p.A658Sfs*46 | Frame Shift Ins (INS) | VAF 40/264 reads (15%) | called by mutect2, pindel, varscan2
- CTNND1 | c.1358_1371del p.V453Afs*8 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | called by pindel, varscan2*
- DENND6A | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXDN | c.3970C>A p.Q1324K | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.325); called by muse, varscan2
- SFTPA1 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, varscan2
- STARD10 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 26/995 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- SURF6 | c.1085G>C p.*362Sext*12 | Nonstop Mutation (SNP) | VAF 90/572 reads (16%) | called by muse, mutect2
- SURF6 | c.993G>C p.R331S | Missense Mutation (SNP) | VAF 123/862 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TMEM229A | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 21/574 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZDHHC13 | c.811del p.T271Qfs*5 | Frame Shift Del (DEL) | VAF 45/339 reads (13%) | called by mutect2, pindel, varscan2
- ZNF165 | c.864C>A p.H288Q | Missense Mutation (SNP) | VAF 93/574 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF446 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 180/342 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF85 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ARHGAP20 | c.990G>A p.R330= | Silent (SNP) | VAF 34/520 reads (7%) | called by muse, mutect2
- B3GALT4 | c.690G>A p.V230= | Silent (SNP) | VAF 88/1875 reads (5%) | called by muse, mutect2
- LMTK3 | c.537C>A p.I179= | Silent (SNP) | VAF 128/403 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.22668C>A p.A7556= | Silent (SNP) | VAF 180/345 reads (52%) | called by muse, varscan2
- SORCS1 | c.1401C>A p.I467= | Silent (SNP) | VAF 72/232 reads (31%) | catalogued as COSV53913580; called by muse, mutect2, varscan2
- HSD11B1L | c.668+96G>C | Intron (SNP) | VAF 95/554 reads (17%) | called by muse, mutect2, varscan2
